Somatic mutation profile of tumor specimen TCGA-AC-A3W7-01A (aliquot TCGA-AC-A3W7-01A-11D-A228-09) from TCGA case TCGA-AC-A3W7, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 66.6 years (24,327 days).
Specimen TCGA-AC-A3W7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c43dbd85-fb31-4416-80e5-7b3dd0ffdc08.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AC-A3W7-10A (Blood Derived Normal), aliquot TCGA-AC-A3W7-10A-01D-A22A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3f72ea22-83c0-4bcd-ae91-6342bf177706

The open-access MAF lists 68 somatic variants for this specimen: 50 protein-altering or splice-affecting, 18 silent.
By variant classification: Missense Mutation 35, Silent 18, Nonsense Mutation 7, Frame Shift Del 5, Splice Site 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 21/73 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA13 | c.11797C>T p.R3933W | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.814); catalogued as rs755420119; called by muse, mutect2, varscan2
- ALDH16A1 | c.2372C>T p.A791V | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.167); catalogued as rs754754057; called by muse, mutect2, varscan2
- B3GALT2 | c.339G>C p.E113D | Missense Mutation (SNP) | VAF 6/144 reads (4%) | SIFT tolerated (0.4); PolyPhen benign (0.038); catalogued as COSV66463845; called by muse, mutect2
- CPT1B | c.733C>T p.R245* | Nonsense Mutation (SNP) | VAF 22/47 reads (47%) | catalogued as rs374942225; called by muse, mutect2, varscan2
- FLG2 | c.4567G>A p.G1523S | Missense Mutation (SNP) | VAF 53/287 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.178); catalogued as rs769383959, COSV101165826; called by muse, mutect2, varscan2
- HACL1 | c.64C>T p.Q22* | Nonsense Mutation (SNP) | VAF 7/58 reads (12%) | catalogued as COSV100329897; called by muse, mutect2, varscan2
- LILRB1 | c.869G>A p.R290K (on ENST00000427581; = p.R254K on NM_006669.6) | Missense Mutation (SNP) | VAF 43/162 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.854); catalogued as rs1490646874; called by muse, mutect2, varscan2
- PSG6 | c.868G>T p.E290* | Nonsense Mutation (SNP) | VAF 18/406 reads (4%) | catalogued as COSV51834537; called by muse, mutect2
- SHANK1 | c.73G>C p.E25Q | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.212); catalogued as COSV53260747; called by muse, mutect2
- SNUPN | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs779696140, COSV57949222; called by muse, mutect2, varscan2
- TAS2R41 | c.350C>G p.S117C | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV68765403; called by muse, mutect2, varscan2
- TMEM169 | c.704C>T p.S235L | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.552); catalogued as rs779968539, COSV55265075; called by muse, mutect2, varscan2
- ZNF544 | c.1591C>T p.Q531* | Nonsense Mutation (SNP) | VAF 8/34 reads (24%) | catalogued as rs1291938648; called by muse, mutect2, varscan2
- ABCA9 | c.1978del p.L660* | Frame Shift Del (DEL) | VAF 6/37 reads (16%) | called by mutect2, pindel, varscan2
- C10orf90 | c.22+1del p.X8_splice | Splice Site (DEL) | VAF 7/48 reads (15%) | called by mutect2, pindel
- CARS1 | c.466C>T p.Q156* | Nonsense Mutation (SNP) | VAF 7/65 reads (11%) | called by muse, mutect2, varscan2
- CCNB3 | c.1973C>G p.S658* | Nonsense Mutation (SNP) | VAF 7/38 reads (18%) | called by muse, mutect2, varscan2
- CDH1 | c.595dup p.T199Nfs*10 | Frame Shift Ins (INS) | VAF 6/16 reads (38%) | called by mutect2, pindel, varscan2
- CENPO | c.391G>C p.E131Q | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- COL11A2 | c.4549G>T p.D1517Y (on ENST00000341947 / NM_080680.3; = p.D1410Y on NM_080679.2) | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DGKK | c.2330T>C p.I777T | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- DHDH | c.203-1G>C p.X68_splice | Splice Site (SNP) | VAF 30/133 reads (23%) | called by muse, mutect2, varscan2
- ELK4 | c.350C>A p.S117Y | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- EPRS1 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- GARRE1 | c.1942G>A p.E648K | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- KNTC1 | c.287G>A p.G96E | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- MRGPRD | c.504G>C p.L168F | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.05); called by muse, mutect2
- NAF1 | c.501G>C p.K167N | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- NTM | c.49G>C p.V17L | Missense Mutation (SNP) | VAF 56/194 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR8K5 | c.647T>A p.V216E | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- PDXDC1 | c.1628del p.N543Tfs*7 | Frame Shift Del (DEL) | VAF 9/58 reads (16%) | called by mutect2, pindel, varscan2
- PKP4 | c.923C>A p.T308N | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- POMT1 | c.373G>T p.E125* | Nonsense Mutation (SNP) | VAF 23/91 reads (25%) | called by muse, mutect2, varscan2
- RBAK | c.800G>T p.G267V | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RSPH1 | c.19G>C p.E7Q | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RUNX1 | c.226_236del p.P76Afs*31 (on ENST00000344691 / NM_001001890.3; = p.P103Afs*31 on NM_001754.5) | Frame Shift Del (DEL) | VAF 13/70 reads (19%) | called by mutect2, pindel, varscan2
- SGCE | c.482A>C p.K161T (on ENST00000647096; = p.K125T on NM_003919.3) | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- SGSM1 | c.1399G>A p.E467K | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC26A2 | c.2056del p.C686Afs*5 | Frame Shift Del (DEL) | VAF 5/33 reads (15%) | called by mutect2, pindel, varscan2
- SPANXN2 | c.181A>G p.T61A | Missense Mutation (SNP) | VAF 69/148 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SPIDR | c.1010G>A p.G337E | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- TNXB | c.4097C>T p.S1366F (on ENST00000647633; = p.S1119F on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- WDR35 | c.2643A>T p.K881N (on ENST00000345530 / NM_001006657.2; = p.K870N on NM_020779.4) | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.581); called by muse, mutect2
- ZBED6CL | c.534_538del p.E179Kfs*24 | Frame Shift Del (DEL) | VAF 13/49 reads (27%) | called by mutect2, pindel, varscan2
- ZNF16 | c.526A>G p.T176A | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF202 | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF544 | c.426C>G p.F142L | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.8); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- ZNF544 | c.923C>A p.S308Y | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- ZNF770 | c.2023C>T p.H675Y | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADSS1 | c.756G>A p.V252= | Silent (SNP) | VAF 12/73 reads (16%) | called by muse, mutect2, varscan2
- CELSR1 | c.2649C>G p.L883= | Silent (SNP) | VAF 14/118 reads (12%) | called by muse, mutect2, varscan2
- EXOG | c.108G>A p.L36= | Silent (SNP) | VAF 62/210 reads (30%) | catalogued as COSV55063872; called by muse, mutect2, varscan2
- IL4I1 | c.495G>A p.K165= | Silent (SNP) | VAF 13/43 reads (30%) | called by muse, mutect2, varscan2
- JUNB | c.246C>T p.L82= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as rs558783117; called by muse, mutect2, varscan2
- LTN1 | c.1101C>T p.I367= | Silent (SNP) | VAF 18/65 reads (28%) | called by muse, mutect2, varscan2
- MUC1 | c.45C>T p.L15= | Silent (SNP) | VAF 14/78 reads (18%) | called by muse, mutect2, varscan2
- NEIL3 | c.1050C>T p.L350= | Silent (SNP) | VAF 20/55 reads (36%) | called by muse, mutect2, varscan2
- PALMD | c.972G>A p.P324= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs145694277; called by muse, mutect2, varscan2
- PLXNA4 | c.3939G>A p.P1313= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs377241563; called by mutect2, varscan2
- PRKAB1 | c.744G>A p.V248= | Silent (SNP) | VAF 7/24 reads (29%) | called by muse, mutect2, varscan2
- SLC5A8 | c.840C>G p.L280= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV73310596; called by muse, mutect2, varscan2
- SMG1 | c.10467C>G p.L3489= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as rs1567312944; called by muse, mutect2, varscan2
- SNX27 | c.1347G>A p.T449= | Silent (SNP) | VAF 18/77 reads (23%) | catalogued as rs781281484, COSV64326523; called by muse, mutect2, varscan2
- SPAM1 | c.1200C>G p.L400= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV99772678; called by muse, mutect2, varscan2
- TPST1 | c.171C>A p.L57= | Silent (SNP) | VAF 19/47 reads (40%) | called by muse, mutect2, varscan2
- TTC21A | c.2205C>T p.G735= | Silent (SNP) | VAF 5/52 reads (10%) | catalogued as rs187725777, COSV57185594; called by mutect2, varscan2
- UCK2 | c.621C>T p.I207= | Silent (SNP) | VAF 36/142 reads (25%) | catalogued as COSV63314368; called by muse, mutect2, varscan2
